Gene-level copy-number profile of tumor specimen HTMCP-01-10-00769-01A from CGCI case HTMCP-01-10-00769, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 63.3 years (23,127 days).
Specimen HTMCP-01-10-00769-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 700715ec-d205-4c9a-8ba2-c32c11e2af5c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-10-00769-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,778 have no estimate.
https://portal.gdc.cancer.gov/files/324cc911-60c4-4067-9bb0-ce29e065081a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 4,753; copy number 2: 42,855; copy number 3: 10,061; copy number 4: 1,097; copy number 5: 56; copy number 6: 1; copy number 8: 2; copy number 10: 3; copy number 11: 1; copy number 29: 12; copy number 159: 3.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:21,794,095–21,795,759, 1 gene: AC092375.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 78 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:9,234,385–9,236,046, 1 gene, copy number 29: USP17L15.
- chr4:9,243,879–9,369,070, 13 genes, copy number 10–29: USP17L17, USP17L18, USP17L23, USP17L24, USP17L25, USP17L26, USP17L5, USP17L27, USP17L28, USP17L29, USP17L9P, USP17L30, USP17L6P.
- chr7:26,276,195–26,376,701, 3 genes, copy number 5 (within-gene range 4–5): AC010677.1, SNX10, AC004540.2.
- chr7:38,239,580–38,330,935, 15 genes, copy number 5 (within-gene range 3–5): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8.
- chr7:43,582,758–43,650,713, 1 gene, copy number 5 (within-gene range 3–5): STK17A.
- chr8:8,783,354–8,893,630, 1 gene, copy number 5: MFHAS1.
- chr8:58,805,412–59,119,147, 1 gene, copy number 5 (within-gene range 4–6): TOX.
- chr8:58,991,720–59,123,478, 2 genes, copy number 5–6: AC105150.1, AC090152.1.
- chr9:64,810,865–64,811,429, 1 gene, copy number 10: BNIP3P4.
- chr9:65,282,101–65,323,015, 2 genes, copy number 8: FOXD4L5, CBWD4P.
- chr12:14,250,232–14,502,935, 4 genes, copy number 5: RNU6-491P, GNAI2P1, RPL30P11, ATF7IP.
- chr12:31,948,334–31,993,107, 3 genes, copy number 5: RPL12P32, AC023050.5, RESF1.
- chr12:47,237,734–47,279,021, 3 genes, copy number 5: AC008083.2, AC008083.3, AC008083.4.
- chr12:56,663,341–56,741,535, 4 genes, copy number 5 (within-gene range 3–5): PTGES3, RN7SL809P, NACA, AC117378.1.
- chr12:68,610,855–68,671,901, 4 genes, copy number 5: RAP1B, RPL10P12, SNORA70G, ATP5PDP4.
- chr12:68,686,951–68,850,686, 8 genes, copy number 5 (within-gene range 3–5): NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2.
- chr12:112,026,689–112,108,796, 1 gene, copy number 5 (within-gene range 3–5): NAA25.
- chr12:112,063,909–112,069,209, 2 genes, copy number 5: AC073575.1, Y_RNA.
- chr12:124,901,512–124,935,895, 4 genes, copy number 5: RNU6-927P, UBC, MIR5188, RPL22P19.
- chr16:28,751,787–28,772,807, 1 gene, copy number 11: NPIPB9.
- chr16:29,380,242–29,380,345, 1 gene, copy number 5: AC025279.3.
- chr16:29,475,064–29,505,999, 3 genes, copy number 159: AC133555.2, AC133555.1, NPIPB12.

Autosomal genes at a single copy (total copy number 1): 1,897. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
